Gene-level copy-number profile of tumor specimen TCGA-78-7153-01A from TCGA case TCGA-78-7153, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Overlapping lesion of lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.5 years (23,922 days).
Specimen TCGA-78-7153-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.553d187a-19e3-4389-926a-11e4ce19a0bd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-78-7153-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cdaca703-662f-41a8-b965-3a4d6ed0720f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 1,933; copy number 3: 19,879; copy number 4: 30,904; copy number 5: 3,171; copy number 6: 2,751; copy number 7: 6; copy number 8: 6; copy number 9: 37; copy number 10: 196; copy number 11: 38; copy number 12: 29; copy number 13: 19; copy number 14: 22; copy number 16: 205; copy number 17: 62; copy number 18: 13; copy number 19: 36; copy number 20: 14; copy number 21: 57; copy number 22: 47; copy number 23: 116; copy number 24: 51; copy number 27: 37; copy number 29: 52; copy number 30: 8; copy number 31: 44; copy number 37: 20; copy number 40: 29; copy number 48: 27; copy number 54: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-78-7153-01A-11D-2035-01): tumor purity 0.57, ploidy 4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,169 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:58,227,578–61,944,180, 51 genes, copy number 24 (within-gene range 2–24): AC092819.3, AC092819.1, AC092819.2, UBXN2B, AC009927.1, CYP7A1, PPIAP85, SDCBP, NSMAF, AC068522.1, TOX, RNU4-50P, AC105150.1, AC090152.1, AC087698.1, RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1, AC107934.2, AC022709.1, AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2, CHD7, AC113143.1, AC113143.2, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3.
- chr8:63,687,179–64,369,176, 1 gene, copy number 23 (within-gene range 2–23): LINC01414.
- chr8:63,769,428–70,104,179, 96 genes, copy number 23–54 (broad region; genes not listed).
- chr8:71,675,300–75,566,834, 75 genes, copy number 29–40 (broad region; genes not listed).
- chr8:79,891,553–91,398,155, 175 genes, copy number 9–30 (within-gene range 6–30) (broad region; genes not listed).
- chr8:92,460,539–92,879,502, 6 genes, copy number 21 (within-gene range 6–21): AC091096.1, AC104211.1, AC104211.3, FLJ46284, AC104211.2, AC117834.2.
- chr8:93,646,066–94,707,466, 34 genes, copy number 11 (within-gene range 5–11): ZNF317P1, CIBAR1, AC120053.1, AC010834.3, RBM12B, AC010834.1, RBM12B-AS1, AC010834.2, TMEM67, AC084346.1, MYL12AP1, PDP1, MIR378D2HG, MIR378D2, PSMA2P2, RPL34P18, AC105081.1, AP003351.1, CDH17, AP003478.1, GEM, RPS4XP10, RAD54B, FSBP, VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1.
- chr8:97,868,840–98,942,827, 16 genes, copy number 17 (within-gene range 5–20): MATN2, RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA, POP1, NIPAL2, RNU6-914P, STK3, AP003355.3, AP003355.1, KCNS2, AP003355.2, RNU6-748P.
- chr8:98,782,055–99,013,743, 9 genes, copy number 20: RPL19P14, AC016877.2, MRPL57P7, RN7SKP85, AC016877.3, OSR2, VPS13B-DT, AC016877.1, AC104986.1.
- chr8:99,091,738–99,120,581, 2 genes, copy number 20: AC107909.2, AC107909.1.
- chr8:102,125,432–102,452,483, 10 genes, copy number 19: MIR5680, AP001328.1, RRM2B, UBR5-AS1, SUMO2P19, UBR5, AP002907.1, AP002981.1, RNU6ATAC8P, HSPE1P14.
- chr8:103,500,696–104,256,094, 1 gene, copy number 12 (within-gene range 6–12): RIMS2.
- chr8:103,768,281–103,769,029, 1 gene, copy number 12: AC090686.1.
- chr8:104,590,733–106,272,902, 17 genes, copy number 12: ZFPM2, AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2.
- chr8:115,408,496–117,176,714, 16 genes, copy number 10–19 (within-gene range 7–19): TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2.
- chr8:118,189,455–118,622,112, 2 genes, copy number 12 (within-gene range 5–12): SAMD12, AC023590.1.
- chr8:120,812,219–122,428,551, 10 genes, copy number 12–20: AC104958.2, AC068413.1, AC011626.1, RPL35AP19, HAS2, HAS2-AS1, LINC02855, AC037486.1, MRPS36P3, SMILR.
- chr8:122,485,515–122,489,815, 1 gene, copy number 20: AC108136.1.
- chr8:122,769,274–122,974,510, 5 genes, copy number 14 (within-gene range 5–14): CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1.
- chr8:123,851,987–125,541,373, 37 genes, copy number 17 (within-gene range 5–48): FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1.
- chr8:125,749,055–125,750,241, 1 gene, copy number 17: AC016074.1.
- chr8:126,474,189–145,066,685, 351 genes, copy number 11–48 (broad region; genes not listed).
- chr20:46,173,739–48,074,188, 47 genes, copy number 22 (within-gene range 4–22): CDH22, SLC35C2, AL133227.1, ELMO2, ZNF663P, AL031686.1, MKRN7P, ZNF840P, ZNF334, OCSTAMP, SLC13A3, AL133520.1, TP53RK, AL031055.1, SLC2A10, RN7SKP33, AL354766.1, EYA2, AL354766.2, GAPDHP54, AL121776.1, AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3, AL034418.1, SULF2, AL354813.1, RNU7-173P, SRMP1, RNA5SP486, RNU7-92P, AL357558.2, AL357558.1, AL357558.3, LINC01522, LINC01523, AL139351.2, AL139351.3, AL139351.1.
- chr20:58,150,902–64,313,132, 205 genes, copy number 10–23 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
